Somatic mutation profile of tumor specimen 0DHV6D from CCDI case PBBUIS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Atypical choroid plexus papilloma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 21.3 years (7,763 days).
Specimen 0DHV6D: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39d8030e-7389-4297-b1bb-bbb74ebbd22a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHV64 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dfd4917c-2490-4ebf-8161-ca4d6b2a68d1

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Intron 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BEND4 | c.721C>A p.Q241K | Missense Mutation (SNP) | VAF 26/860 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.217); catalogued as rs1357690011, COSV72468907; called by muse, mutect2
- DAO | c.194+1G>A p.X65_splice | Splice Site (SNP) | VAF 66/1114 reads (6%) | catalogued as rs762930737, CS155533, COSV57323690; called by muse, mutect2
- HYDIN | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 129/834 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55479080; called by muse, mutect2, varscan2
- NDUFA5 | c.22-6G>T | Splice Region (SNP) | VAF 52/885 reads (6%) | catalogued as COSV63252284; called by muse, mutect2
- SLC51A | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 148/711 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1269564751; called by muse, mutect2, varscan2
- HECW1 | c.1281C>G p.D427E | Missense Mutation (SNP) | VAF 188/1136 reads (17%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHB9 | c.1308C>A p.S436R | Missense Mutation (SNP) | VAF 192/879 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ZNF251 | c.1850C>G p.T617S | Missense Mutation (SNP) | VAF 169/1007 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- FAM160A1 | c.2382A>G p.G794= | Silent (SNP) | VAF 224/1340 reads (17%) | called by muse, mutect2, varscan2
- NPAP1 | c.264G>A p.V88= | Silent (SNP) | VAF 116/1353 reads (9%) | catalogued as rs1288931573, COSV100275135; called by muse, mutect2
- PPP3CB | c.1023A>G p.R341= | Silent (SNP) | VAF 106/1102 reads (10%) | called by muse, mutect2
- PPARGC1B | c.2971+65G>C | Intron (SNP) | VAF 12/240 reads (5%) | called by muse, mutect2
